Somatic mutation profile of cancer-model specimen HCM-BROD-0012-C71-85A (Adherent Cell Line, passage 13; aliquot HCM-BROD-0012-C71-85A-01D-A768-36), derived from the primary tumor of HCMI case HCM-BROD-0012-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 56.8 years (20,744 days).
Specimen HCM-BROD-0012-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 13.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5519526d-878a-4a7e-8899-bc308766646a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0012-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0012-C71-10A-01D-A768-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2577d96f-7edb-4f4b-9075-b4646e4da6f0

The open-access MAF lists 78 somatic variants for this specimen: 46 protein-altering or splice-affecting, 19 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 19, Intron 5, Splice Site 5, RNA 3, 5'UTR 2, 3'UTR 2, Nonsense Mutation 1, Frame Shift Ins 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP7A | c.1996G>A p.G666R | Missense Mutation (SNP) | VAF 186/397 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs797045344, CM109533; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GLA | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 142/272 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as rs104894827, CM890057; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.188A>G p.Y63C | Missense Mutation (SNP) | VAF 118/238 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121918459, CM013416, COSV61007856; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AL645922.1 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 300/621 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs753059312, COSV54960912; called by muse, mutect2, varscan2
- ALG5 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99523601; called by muse, mutect2, varscan2
- ARSF | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 137/336 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs201726785; called by muse, mutect2, varscan2
- CBY2 | c.1249G>A p.V417M | Missense Mutation (SNP) | VAF 108/228 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV60119502; called by muse, mutect2, varscan2
- CNTNAP5 | c.2104C>T p.R702W | Missense Mutation (SNP) | VAF 72/144 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1207750958, COSV70472432, COSV70483251; called by muse, mutect2, varscan2
- EXOC3L1 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 122/245 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139069832; called by muse, mutect2, varscan2
- FAM186A | c.580del p.I194Yfs*16 | Frame Shift Del (DEL) | VAF 20/46 reads (43%) | catalogued as rs1260976214; called by mutect2, pindel, varscan2
- ISG20 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 115/236 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs549880749, COSV60143590; called by muse, mutect2, varscan2
- KANK4 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 94/182 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.083); catalogued as rs759887895; called by muse, mutect2, varscan2
- KCNH3 | c.2072G>A p.R691H | Missense Mutation (SNP) | VAF 150/321 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs763321479, COSV57793215; called by muse, mutect2, varscan2
- MAGEB6 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs770333290, COSV100983635, COSV66873231; called by muse, mutect2, varscan2
- NF2 | c.1341-2A>C p.X447_splice | Splice Site (SNP) | VAF 240/473 reads (51%) | catalogued as CS115647, COSV58527036; called by muse, mutect2, varscan2
- PCDH15 | c.4212-2A>C p.X1404_splice | Splice Site (SNP) | VAF 110/258 reads (43%) | catalogued as COSV57412888; called by muse, mutect2, varscan2
- PRKX | c.443C>T p.T148M | Missense Mutation (SNP) | VAF 150/796 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.984); catalogued as rs751945456; called by muse, mutect2, varscan2
- RHBDL1 | c.341C>T p.A114V (on ENST00000219551 / NM_001318733.2; = p.A49V on NM_001278720.2) | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1176173464; called by muse, mutect2, varscan2
- SCN5A | c.4226A>T p.Y1409F (on ENST00000333535 / NM_198056.3; = p.Y1408F on NM_000335.5) | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as CM100717; called by muse, varscan2
- SLCO4C1 | c.1844T>C p.L615S | Missense Mutation (SNP) | VAF 42/211 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1416876929; called by muse, mutect2, varscan2
- STARD6 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV100323564; called by muse, mutect2
- TNIP2 | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 132/268 reads (49%) | catalogued as rs556774838; called by muse, mutect2, varscan2
- TPTE2 | c.593A>G p.E198G (on ENST00000400230 / NM_199254.2; = p.E121G on NM_130785.3) | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.477); catalogued as rs1305168994; called by muse, mutect2, varscan2
- ZNF234 | c.1169A>G p.H390R | Missense Mutation (SNP) | VAF 151/341 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753238363, COSV70604230; called by muse, mutect2, varscan2
- ZNF536 | c.1447G>A p.G483R | Missense Mutation (SNP) | VAF 79/80 reads (99%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.708); catalogued as rs755613678, COSV100835485, COSV100835753; called by muse, mutect2, varscan2
- BOK | c.45G>A p.M15I | Missense Mutation (SNP) | VAF 151/303 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ENOX2 | c.340+1_340+2del p.X114_splice (on ENST00000338144 / NM_001382520.1; = p.X85_splice on NM_006375.3 and 2 other RefSeq transcripts) | Splice Site (DEL) | VAF 42/87 reads (48%) | called by mutect2, pindel, varscan2
- FAM205A | c.3273G>C p.K1091N | Missense Mutation (SNP) | VAF 13/352 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.023); called by muse, mutect2
- GLUD1 | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 108/243 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GNAL | c.547-1G>A p.X183_splice (on ENST00000269162 / NM_001142339.3; = p.X260_splice on NM_182978.4) | Splice Site (SNP) | VAF 58/121 reads (48%) | called by muse, mutect2, varscan2
- HOXA10 | c.941C>A p.P314Q | Missense Mutation (SNP) | VAF 279/638 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ITGB2 | c.244A>G p.T82A | Missense Mutation (SNP) | VAF 18/229 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- KATNAL1 | c.1013-1G>A p.X338_splice | Splice Site (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- KCTD8 | c.902T>C p.F301S | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- LCMT1 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 66/107 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LRTM2 | c.706G>A p.G236R | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LUC7L2 | c.1024G>C p.D342H | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MYH4 | c.4389G>T p.K1463N | Missense Mutation (SNP) | VAF 81/146 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPIPB15 | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 385/1305 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.351); called by muse, varscan2
- PSMC5 | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- QKI | c.325dup p.T109Nfs*6 | Frame Shift Ins (INS) | VAF 65/84 reads (77%) | called by mutect2, pindel, varscan2
- RAB40AL | c.454T>G p.F152V | Missense Mutation (SNP) | VAF 275/547 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- RPIA | c.677G>A p.S226N | Missense Mutation (SNP) | VAF 81/163 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- SHROOM4 | c.220C>A p.L74I | Missense Mutation (SNP) | VAF 196/365 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TIMM29 | c.388T>A p.C130S | Missense Mutation (SNP) | VAF 189/420 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- UMOD | c.266C>G p.S89C | Missense Mutation (SNP) | VAF 15/550 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCA1 | c.1320G>A p.L440= | Silent (SNP) | VAF 380/381 reads (100%) | called by muse, mutect2, varscan2
- ANKRD10 | c.138C>A p.P46= | Silent (SNP) | VAF 69/418 reads (17%) | called by muse, mutect2, varscan2
- CLEC17A | c.714G>A p.Q238= | Silent (SNP) | VAF 67/132 reads (51%) | called by muse, mutect2, varscan2
- DEPP1 | c.339G>A p.Q113= | Silent (SNP) | VAF 14/266 reads (5%) | called by muse, mutect2
- DOC2B | c.471C>T p.D157= | Silent (SNP) | VAF 66/140 reads (47%) | called by muse, mutect2, varscan2
- EFCC1 | c.315C>T p.S105= | Silent (SNP) | VAF 68/131 reads (52%) | called by muse, mutect2, varscan2
- GUF1 | c.99G>A p.A33= | Silent (SNP) | VAF 128/235 reads (54%) | catalogued as COSV55785447; called by muse, mutect2, varscan2
- IQSEC3 | c.3219A>G p.R1073= | Silent (SNP) | VAF 15/120 reads (13%) | called by muse, mutect2, varscan2
- ITGA11 | c.3084C>T p.D1028= | Silent (SNP) | VAF 87/179 reads (49%) | catalogued as rs61729773; called by muse, mutect2, varscan2
- KCNB2 | c.1524C>T p.F508= | Silent (SNP) | VAF 95/226 reads (42%) | catalogued as rs752821146, COSV73049012; called by muse, mutect2, varscan2
- MCF2L | c.3087C>T p.D1029= (on ENST00000375608; = p.D997= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 58/120 reads (48%) | catalogued as rs781264646, COSV56181082; called by muse, mutect2, varscan2
- MEX3D | c.1212C>T p.A404= | Silent (SNP) | VAF 50/92 reads (54%) | catalogued as rs1415261817; called by muse, mutect2, varscan2
- MRI1 | c.1056C>T p.A352= (on ENST00000040663 / NM_001031727.4; = p.A305= on NM_032285.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 64/152 reads (42%) | called by muse, mutect2, varscan2
- NOTCH3 | c.3222G>A p.E1074= | Silent (SNP) | VAF 119/513 reads (23%) | called by muse, mutect2, varscan2
- OR51F1 | c.576T>C p.D192= | Silent (SNP) | VAF 49/110 reads (45%) | called by muse, mutect2, varscan2
- OR5M8 | c.111G>A p.T37= | Silent (SNP) | VAF 87/192 reads (45%) | catalogued as rs376992051; called by muse, mutect2, varscan2
- PTPRB | c.5454G>A p.A1818= | Silent (SNP) | VAF 45/92 reads (49%) | catalogued as rs369428514; called by muse, mutect2, varscan2
- TANC1 | c.5154C>T p.P1718= | Silent (SNP) | VAF 166/313 reads (53%) | catalogued as COSV55096794; called by muse, mutect2, varscan2
- UPF1 | c.1764G>A p.L588= (on ENST00000599848 / NM_001297549.2; = p.L577= on NM_002911.4) | Silent (SNP) | VAF 88/150 reads (59%) | catalogued as COSV53198280; called by muse, mutect2, varscan2
- ACSF3 | c.*1242C>T | 3'UTR (SNP) | VAF 145/317 reads (46%) | called by muse, mutect2, varscan2
- CCDC74A | c.250+190G>A | Intron (SNP) | VAF 180/349 reads (52%) | called by muse, mutect2, varscan2
- CTDP1 | chr18:79679572 G>T | 5'Flank (SNP) | VAF 70/349 reads (20%) | called by mutect2, varscan2
- EPB41 | c.1845+36T>G | Intron (SNP) | VAF 143/319 reads (45%) | called by muse, mutect2, varscan2
- FASTKD2 | c.1899-18G>A | Intron (SNP) | VAF 145/288 reads (50%) | called by muse, mutect2, varscan2
- GVINP1 | n.4279G>C | RNA (SNP) | VAF 109/211 reads (52%) | called by muse, mutect2, varscan2
- H2AZ2 | c.*15C>T | 3'UTR (SNP) | VAF 49/105 reads (47%) | called by muse, mutect2, varscan2
- MMP26 | c.-145+92644T>A | Intron (SNP) | VAF 131/268 reads (49%) | called by muse, mutect2, varscan2
- PPIL6 | c.-9G>A | 5'UTR (SNP) | VAF 12/12 reads (100%) | called by muse, mutect2
- TRAV38-2DV8 | c.-18C>T | 5'UTR (SNP) | VAF 51/101 reads (50%) | called by muse, mutect2, varscan2
- XIST | n.10941T>A | RNA (SNP) | VAF 73/130 reads (56%) | called by muse, mutect2, varscan2
- XIST | n.7432_7433del | RNA (DEL) | VAF 82/271 reads (30%) | catalogued as rs1047292168; called by mutect2, pindel, varscan2
- ZNF385A | c.421+1003A>G | Intron (SNP) | VAF 2/13 reads (15%) | called by muse, mutect2
